Gene-level copy-number profile of tumor specimen C3N-02757-01 (profiled together with C3N-02757-02) from CPTAC case C3N-02757, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.8 years (25,121 days).
Specimen C3N-02757-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 13268252-73bf-475f-ba86-4d1feeb6d867.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02757-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/bc662900-4f7c-4732-8e83-d766425873d1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 3,409; copy number 2: 19,238; copy number 3: 18,749; copy number 4: 16,132; copy number 5: 1,039; copy number 6: 1; copy number 7: 200; copy number 9: 2; copy number 10: 8; copy number 36: 2.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–4): AL627309.3.
- chr2:739,588–740,164, 1 gene: AC116609.3.
- chr9:15,553,043–16,410,990, 4 genes (within-gene range 0–2): CCDC171, HMGN2P16, RNU6-14P, C9orf92.
- chr9:16,473,188–16,476,237, 1 gene (within-gene range 0–2): AL449983.1.
- chr9:20,999,509–23,956,444, 68 genes (broad region; genes not listed).
- chr9:41,126,430–41,701,096, 22 genes (within-gene range 0–1): FOXD4L6, CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4.
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr9:64,621,560–64,889,063, 9 genes: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr16:32,388,135–32,458,758, 3 genes: AC138915.2, PABPC1P13, AC138915.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 212 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:169,552,449–172,203,454, 40 genes, copy number 7: RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2, USP12P1, AC091980.2, TLX3, AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1, AC011410.1, SMIM23, FBXW11, STK10, EFCAB9.
- chr5:173,383,941–179,083,977, 160 genes, copy number 7 (broad region; genes not listed).
- chr7:5,419,827–5,513,809, 8 genes, copy number 10 (within-gene range 6–10): AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.
- chr16:32,188,333–32,193,530, 2 genes, copy number 9: AC133485.5, AC133485.4.
- chr16:32,356,981–32,380,049, 2 genes, copy number 36: AC133548.1, ACTR3BP3.

Autosomal genes at a single copy (total copy number 1): 2,897. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
